Gene-level copy-number profile of tumor specimen C3L-03382-01 from CPTAC case C3L-03382, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 71.6 years (26,136 days).
Specimen C3L-03382-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a4696272-45c1-48e0-86fc-999b89ac2f4c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03382-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,736 have no estimate.
https://portal.gdc.cancer.gov/files/1cf05ebf-03b9-4a02-afb9-bab5f03324c6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 524; copy number 1: 3,200; copy number 2: 48,960; copy number 3: 6,200; copy number 5: 3.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:41,979,352–42,213,918, 6 genes: CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3.
- chr9:64,462,819–64,498,745, 6 genes: CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:79,762,371–79,802,842, 2 genes, copy number 5 (within-gene range 3–5): HEY1, LINC01607.
- chr8:79,800,133–79,800,195, 1 gene, copy number 5 (within-gene range 3–5): RNU7-85P.

Autosomal genes at a single copy (total copy number 1): 856. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
